Gene-level copy-number profile of tumor specimen TCGA-D8-A27W-01A from TCGA case TCGA-D8-A27W, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 55.2 years (20,173 days).
Specimen TCGA-D8-A27W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.4a98e514-5c43-4d64-a7e6-8a8d59b89f25.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D8-A27W-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/187b8ad4-fd62-4f0b-955a-2168ee2d9052

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 3,719; copy number 3: 12,243; copy number 4: 19,226; copy number 5: 7,599; copy number 6: 7,758; copy number 7: 6,345; copy number 8: 1,161; copy number 9: 91; copy number 11: 204; copy number 12: 96; copy number 13: 128; copy number 14: 1,173; copy number 15: 76.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D8-A27W-01A-11D-A16C-01): tumor purity 0.44, ploidy 4.59, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,768 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:25,632,673–26,206,038, 46 genes, copy number 9: AL022170.1, SCGN, PRELID1P2, H2AC1, H2BC1, H2BC2P, H2AC2P, SLC17A4, SLC17A1, SLC17A3, H2AC3P, H2BP5, SLC17A2, TRIM38, U91328.2, U91328.1, U91328.3, H3P26, H1-1, H3C1, H4C1, H4C2, H3C2, H2AC4, H2BC3, H2AC5P, H3C3, H1-2, HFE, H4C3, H1-6, H2BC4, H2AC6, H1-4, H2BC5, AL353759.1, LARP1P1, H2BC6, H4C4, H1-12P, AL031777.2, H3C4, H2AC7, H2BC7, AL031777.1, H4C5.
- chr6:34,018,643–35,728,583, 50 genes, copy number 15 (within-gene range 2–15): GRM4, KRT18P9, CYCSP55, HMGA1, MIR6835, SMIM29, AL354740.1, RPL35P2, NUDT3, RPS10-NUDT3, RPS10, PACSIN1, SPDEF, IFITM3P3, ILRUN, RPL7P25, RN7SL200P, AL031577.1, AL451165.2, AL451165.1, AL139100.1, SNRPC, UHRF1BP1, Y_RNA, RNY3P15, TAF11, ANKS1A, HSPE1P11, AL591002.1, AL138721.1, TCP11, SCUBE3, Z97832.2, ZNF76, Z97832.1, DEF6, PPARD, MKRN6P, FANCE, RPL10A, MIR7111, TEAD3, TULP1, AL033519.4, AL033519.3, FKBP5, AL033519.2, AL033519.5, AL033519.1, MIR5690.
- chr6:36,442,767–36,491,143, 1 gene, copy number 13 (within-gene range 2–13): KCTD20.
- chr6:36,493,892–37,571,460, 38 genes, copy number 13: STK38, RN7SL748P, SRSF3, MIR3925, RNU1-88P, Y_RNA, PANDAR, LAP3P2, CDKN1A, DINOL, RAB44, Z85996.1, CPNE5, Z85996.2, Z85996.3, PPIL1, C6orf89, AL122034.1, PI16, MTCH1, FGD2, COX6A1P2, RPL12P2, PIM1, TMEM217, AL353579.1, TBC1D22B, AL096712.1, AL096712.2, RNF8, RN7SL273P, CMTR1, CCDC167, LINC02520, AL353597.2, AL353597.1, MIR4462, AL353597.3.
- chr8:29,905,735–30,921,335, 34 genes, copy number 12: AC131254.2, LINC02209, MIR3148, MAP2K1P1, RNU6-1218P, SARAF, AC044849.1, LEPROTL1, RPS15AP24, MBOAT4, AC026979.2, DCTN6, AC026979.1, AC026979.4, AC026979.3, HSPA8P11, AC090820.1, AC090820.2, AC109329.1, PPIAP84, TUBBP1, RBPMS-AS1, RBPMS, AC102945.2, GTF2E2, AC102945.1, SMIM18, RNU5A-3P, GSR, UBXN8, HIKESHIP3, PPP2CB, TEX15, AC090281.1.
- chr8:37,421,341–38,144,076, 30 genes, copy number 14 (within-gene range 2–14): LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1.
- chr8:43,018,424–135,456,952, 1,334 genes, copy number 9–15 (broad region; genes not listed).
- chr8:135,859,369–137,092,183, 1 gene, copy number 13 (within-gene range 3–14): LINC02055.
- chr8:137,105,352–141,195,808, 33 genes, copy number 14 (within-gene range 2–14): RNU6-144P, ZYXP1, AC105213.1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B, COL22A1, AC027541.1, AC100807.1, AC100807.2, AC087354.1, AC090093.1, KCNK9, TRAPPC9, AC021744.1, C8orf17, AC040978.1, PEG13, AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD, PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1.
- chr8:141,326,130–145,066,685, 184 genes, copy number 11 (broad region; genes not listed).
- chr11:69,072,915–69,162,440, 1 gene, copy number 9 (within-gene range 4–9): AP003071.5.
- chr11:69,103,493–69,738,017, 16 genes, copy number 9 (within-gene range 4–9): AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
